Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JO, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JO-06A (Metastatic).

DIAGNOSIS

Patient ID – Sample ID -

(A) LEFT AXILLARY CONTENTS:

METASTATIC MELANOMA IN SOFT TISSUE.

TUMOR SIZE: 95.0 X 40.0 MM.

TUMOR NECROSIS IS PRESENT (30% ON REPRESENTATIVE SECTIONS)

Sixteen lymph nodes (melanoma not identified) (0/16).

Scar.

ICD-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous tissue,

axilla C49.3

for 7/24/11

GROSS DESCRIPTION

(A) LEFT AXILLARY CONTENTS - Received is a fragment of fibroadipose tissue with attached unoriented strip of tan skin (fatty tissue measures 15.0 x 15.0 x 3.0 cm). Skin measures 14.5 x 1.0 cm. Skin surface contains a focally friable otherwise well-healed scar measuring 12.0 cm in length. Sectioning of the fatty tissue reveals centrally cystic, diffusely necrotic, gray-red nodule measuring 9.5 x 4.0 x 3.5 cm. Cystic portion of the nodule is filled with hemorrhagic fluid. Portion of the nodule is submitted for the aforementioned studies and melanoma bank. Further dissection of the fatty tissue reveals multiple possible lymph nodes ranging from 0.4 up to 2.2 cm in greatest dimension. Tissue beneath scar is dense, fibrotic. Entire smaller lymph nodes, representative sections of the nodule and skin with the scar are submitted.

SECTION CODE: A1-A3, representative sections of the nodule; A4, two possible lymph nodes; A5, four possible lymph nodes; A6, one sectioned possible lymph node; A7, one sectioned possible lymph node; A8, one sectioned possible lymph node; A9, one sectioned possible lymph node; A10, one sectioned possible lymph node; A11, one sectioned possible lymph node; A12, one sectioned possible lymph node; A13, one sectioned possible lymph node; A14, one sectioned possible lymph node; A15, A16, one sectioned possible lymph node; A17, representative section of the skin.

CLINICAL HISTORY

Metastatic melanoma, for and studies.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

1. These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 9629afe6-11cb-45f4-950d-4a8fb0725527 (TCGA-D3-A2JO.526BF4D7-C1DD-4128-9274-50AEF7DA463D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).